Gene-level copy-number profile of tumor specimen TCGA-75-5146-01A from TCGA case TCGA-75-5146, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-5146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1ed4a883-d255-4d45-8ef5-4d9ae896796f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-75-5146-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf509449-c99e-41c6-86a3-3e0a7d61d694

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 135; copy number 1: 18,300; copy number 2: 37,651; copy number 3: 3,377; copy number 4: 127; copy number 7: 51; copy number 8: 16; copy number 9: 153.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-75-5146-01A-01D-1624-01): tumor purity 0.58, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 220 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:9,505,180–9,839,076, 5 genes, copy number 7 (within-gene range 2–7): LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1.
- chr20:11,800,463–11,926,609, 5 genes, copy number 8: LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1.
- chr20:22,220,554–26,251,546, 117 genes, copy number 7–9 (broad region; genes not listed).
- chr20:35,615,829–36,270,918, 28 genes, copy number 9: SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2.
- chr20:38,378,825–38,435,409, 9 genes, copy number 7: AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D.
- chr20:38,926,312–39,663,552, 11 genes, copy number 8: FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1.
- chr20:41,684,986–43,304,679, 14 genes, copy number 7: RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2.
- chr20:46,345,980–47,656,877, 31 genes, copy number 9 (within-gene range 1–9): SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3.

Autosomal genes at a single copy (total copy number 1): 16,028. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
